CCDI case PBBLWW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ddcc95c1-4867-4af1-b7e2-7518ce254bf5

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,180 days).

Biospecimens (3 samples)
- Sample 0DCM11: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCM19: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCM1G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
